Gene-level copy-number profile of tumor specimen TCGA-24-1846-01A from TCGA case TCGA-24-1846, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.3 years (16,534 days).
Specimen TCGA-24-1846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8426d54f-4075-4012-a5e6-59d4237db996.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1846-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21caea90-9992-4336-8594-72298e7d0e07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 25,016; copy number 2: 28,583; copy number 3: 5,729; copy number 4: 333; copy number 5: 149.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1846-01A-01D-0577-01): tumor purity 0.9, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 102 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:195,658,062–195,739,964, 1 gene, copy number 5 (within-gene range 3–5): MUC20-OT1.
- chr3:195,699,401–198,222,513, 101 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24,477. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
